Somatic mutation profile of tumor specimen ALCH-B46S-TTP1-A (aliquot ALCH-B46S-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B46S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.6 years (25,772 days).
Specimen ALCH-B46S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3cdf051-6356-47f6-9585-5a9dd8219bef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B46S-NB1-A (Blood Derived Normal), aliquot ALCH-B46S-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adcb52fc-79b9-4939-9229-8cb998f26da3

The open-access MAF lists 259 somatic variants for this specimen: 184 protein-altering or splice-affecting, 52 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 52, Nonsense Mutation 14, Intron 11, RNA 5, Splice Site 4, 5'Flank 3, 3'UTR 3, Splice Region 2, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 23/386 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCC5 | c.2380-1G>T p.X794_splice | Splice Site (SNP) | VAF 19/185 reads (10%) | catalogued as COSV55594768; called by muse, mutect2
- ADGRB3 | c.3121A>G p.I1041V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV53265210; called by muse, mutect2
- ARMC3 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs751529638; called by muse, mutect2, varscan2
- BAHCC1 | c.4466G>T p.R1489L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374320761, COSV100311654; called by muse, mutect2, varscan2
- CCDC185 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 10/167 reads (6%) | catalogued as COSV64821204; called by muse, mutect2
- CHRM2 | c.1196C>A p.T399N | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100281453; called by muse, mutect2
- CMYA5 | c.2514G>C p.K838N | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV71405822; called by muse, mutect2
- COLEC12 | c.1740del p.G581Afs*65 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs750635929, COSV68369940; called by pindel, varscan2
- DDR2 | c.2008G>T p.E670* | Nonsense Mutation (SNP) | VAF 75/514 reads (15%) | catalogued as COSV63369578, COSV63370287; called by muse, mutect2, varscan2
- FAM155B | c.378del p.A127Pfs*98 | Frame Shift Del (DEL) | VAF 11/103 reads (11%) | catalogued as rs1569256905, COSV52935612; called by mutect2, pindel, varscan2
- FANCM | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs752364451; ClinVar: uncertain significance; called by muse, mutect2
- FAT1 | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101499472; called by muse, mutect2
- FAT3 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs750752165, COSV53098020; called by muse, mutect2, varscan2
- FMR1NB | c.473G>T p.R158I | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as COSV100789519; called by muse, mutect2
- GPR161 | c.342C>G p.S114R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54788763; called by muse, mutect2
- HOXA1 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58030691; called by muse, mutect2
- KANSL1L | c.2781G>A p.M927I | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs1463607395; called by muse, mutect2
- KLHL4 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as rs776535078, COSV64144614, COSV64145221; called by muse, mutect2
- KRT76 | c.1104C>A p.S368R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60121013; called by muse, mutect2
- LPA | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100307898, COSV100308042; called by muse, mutect2
- MAGEA4 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52342104; called by muse, mutect2
- MAP7D3 | c.1516G>C p.G506R | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV60170395; called by muse, mutect2, varscan2
- MON1B | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as rs1344295758; called by muse, mutect2
- MYH15 | c.4829A>T p.Q1610L | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769365824; called by muse, mutect2
- MYLK2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1227080359; called by muse, mutect2
- NAV1 | c.4870G>C p.V1624L | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55216326; called by muse, mutect2
- NF1 | c.8210C>T p.A2737V (on ENST00000358273 / NM_001042492.3; = p.A2716V on NM_000267.3) | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV62201806; called by muse, mutect2
- NLRP10 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 26/406 reads (6%) | catalogued as COSV60779220; called by muse, mutect2
- NVL | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 30/382 reads (8%) | catalogued as COSV99894597; called by muse, mutect2
- OR10G2 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.936); catalogued as rs559017607; called by muse, mutect2
- OR11H12 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 32/656 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73543902; called by muse, mutect2
- OR2J3 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65849581; called by muse, mutect2
- OR2M3 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV101513424; called by muse, mutect2, varscan2
- OR51B4 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV66517078; called by muse, mutect2, varscan2
- OR9Q1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59038731, COSV59040427; called by muse, mutect2, varscan2
- P2RY13 | c.566C>A p.S189* | Nonsense Mutation (SNP) | VAF 26/545 reads (5%) | catalogued as COSV56402995; called by muse, mutect2
- PRDM9 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 24/535 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57004159, COSV99691416; called by muse, mutect2
- RYR2 | c.8185C>A p.H2729N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63694556; called by muse, mutect2
- SELENOO | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as rs776240322, COSV66600661; called by muse, mutect2
- SLC17A6 | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408660137; called by muse, mutect2
- SV2A | c.1729C>A p.L577M | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as COSV64965604; called by muse, mutect2, varscan2
- TCF23 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV99940264; called by muse, mutect2
- TENM1 | c.5761C>A p.R1921S | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.267); catalogued as COSV100950624, COSV64432631; called by muse, mutect2
- TMC1 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 60/642 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52774156; called by muse, mutect2
- TMEM109 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 48/596 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772917152; called by muse, mutect2
- TPO | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 11/341 reads (3%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.683); catalogued as rs929014692; called by muse, mutect2
- TUBA3E | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs199933182, COSV99919767; called by muse, mutect2
- UBXN7 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.165); catalogued as COSV56357357; called by muse, mutect2
- USH2A | c.5615C>G p.A1872G | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as CD149645; called by muse, mutect2
- ZFHX4 | c.4316C>T p.A1439V | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99257482; called by muse, mutect2, varscan2
- ZFP82 | c.829A>G p.T277A | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67566976; called by muse, mutect2
- ZNF678 | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757139099; called by muse, mutect2
- ZNF831 | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100926251, COSV64041638; called by muse, mutect2, varscan2
- ABCB5 | c.1358G>T p.R453I (on ENST00000404938 / NM_001163941.2; = p.R8I on NM_178559.6) | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- ABCC5 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ACACB | c.4243C>G p.L1415V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK2 | c.8884G>T p.V2962F | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- AP1G2 | c.2177A>T p.Q726L | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- API5 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ATP6V0B | c.521T>A p.V174E | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- B3GALT2 | c.351T>G p.S117R | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2
- BIRC6 | c.12088G>T p.E4030* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- BLVRA | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 23/360 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- BPIFA1 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2
- C16orf78 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- C16orf96 | c.2462G>T p.S821I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CASR | c.1912C>T p.H638Y (on ENST00000490131; = p.H715Y on NM_000388.4) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.453); called by muse, mutect2
- CBLL2 | c.846T>A p.Y282* | Nonsense Mutation (SNP) | VAF 27/337 reads (8%) | called by muse, mutect2
- CCNT2 | c.973A>T p.S325C | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.321); called by muse, mutect2
- CDH9 | c.2188C>A p.P730T | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNKSR2 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2
- COL12A1 | c.3522G>A p.M1174I | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.286); called by muse, mutect2
- COL9A3 | c.1529C>A p.T510K | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); called by muse, mutect2
- CPNE7 | c.1306T>G p.L436V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CR1 | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 25/442 reads (6%) | called by muse, mutect2
- CRTAP | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 40/548 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.847); called by muse, mutect2
- CRY1 | c.426T>A p.N142K | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CSMD2 | c.6267T>A p.F2089L | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.3188G>C p.C1063S (on ENST00000297405 / NM_001363185.1; = p.C959S on NM_052900.3) | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- DCLRE1A | c.1934A>T p.Q645L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2
- DDX3X | c.307T>A p.Y103N (on ENST00000399959; = p.Y104N on NM_001356.5) | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.865); called by muse, mutect2
- DOCK2 | c.4227C>G p.F1409L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.943); called by muse, mutect2
- E2F7 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- EGFLAM | c.2322C>G p.D774E | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.052); called by muse, mutect2
- EIF3L | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.342); called by muse, mutect2
- EIF4G2 | c.1710A>T p.E570D | Missense Mutation (SNP) | VAF 33/457 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- ENOX2 | c.27G>T p.W9C | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- EPHA1 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRRB | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2
- FAM90A1 | c.1327C>G p.P443A | Missense Mutation (SNP) | VAF 12/462 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.036); called by muse, mutect2
- FCGBP | c.5416A>T p.S1806C | Missense Mutation (SNP) | VAF 32/808 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- FSHB | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.083); called by muse, mutect2
- GATB | c.1012A>C p.M338L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2
- GDI1 | c.991+5G>C | Splice Region (SNP) | VAF 26/415 reads (6%) | called by muse, mutect2
- GFRA2 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2
- GFRA3 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- GIN1 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC3 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- HELZ2 | c.4576A>T p.K1526* (on ENST00000467148 / NM_001037335.2; = p.K957* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- HHIPL2 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 74/526 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV1OR15-9 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- IL1RN | c.65A>T p.E22V (on ENST00000409930 / NM_173842.3; = p.E4V on NM_000577.5) | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- ITGA4 | c.1493T>A p.L498Q | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- KIR3DL1 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2
- KRTAP25-1 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); called by mutect2, varscan2
- LAMA1 | c.4097C>T p.P1366L | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.075); called by muse, mutect2
- LAMA4 | c.4120G>T p.A1374S (on ENST00000230538 / NM_001105206.3; = p.A1367S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- LGR4 | c.2431G>T p.D811Y | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LIPI | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 10/341 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- LRP1B | c.10547C>A p.T3516K | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.096); called by muse, mutect2
- LRRC4B | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI2 | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAN1C1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.027); called by muse, mutect2
- MEI1 | c.2315T>G p.L772R | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MUC16 | c.3088C>A p.P1030T | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2
- MYO1B | c.1375A>T p.M459L | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2
- MYOM3 | c.4144C>A p.R1382S | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.091); called by muse, mutect2
- NACA2 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 34/517 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- NCAPH | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCKAP5L | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NDC1 | c.1066G>C p.G356R | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NIBAN3 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOTCH4 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- NRXN3 | c.511G>T p.G171C (on ENST00000557594 / NM_001272020.2; = p.G803C on NM_004796.6) | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OPN1LW | c.65G>C p.S22T | Missense Mutation (SNP) | VAF 8/279 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.076); called by muse, mutect2
- OR2A5 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2
- OR2B11 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- OR2L13 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.368); called by muse, mutect2
- OR5L1 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.365); called by muse, mutect2
- OR5M11 | c.317T>A p.L106H | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- OR5T1 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2
- OR5T1 | c.821C>A p.P274Q | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2
- OSBP | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- OTUD6A | c.511C>G p.R171G | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAK5 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- PCDH15 | c.5444C>A p.P1815Q | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2
- PCDHB4 | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- PCSK1 | c.623A>T p.H208L | Missense Mutation (SNP) | VAF 54/558 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHIP | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PPP6C | c.533C>G p.T178S | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.082); called by muse, mutect2
- PRG4 | c.2891C>A p.T964K | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- PRICKLE3 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by mutect2, varscan2
- PSG6 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); called by muse, mutect2
- PSME4 | c.4479A>T p.K1493N | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.347); called by muse, mutect2
- PTPN5 | c.1219-2A>T p.X407_splice | Splice Site (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- PTPRB | c.3692G>T p.G1231V | Missense Mutation (SNP) | VAF 53/565 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- RAP1GAP | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2
- RASSF8 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RBM33 | c.2723A>C p.K908T | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- REG1A | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- RELN | c.1171A>T p.I391F | Missense Mutation (SNP) | VAF 43/564 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.157); called by muse, mutect2
- RETREG1 | c.808+2T>C p.X270_splice (on ENST00000306320 / NM_001034850.2; = p.X129_splice on NM_019000.4) | Splice Site (SNP) | VAF 20/249 reads (8%) | called by muse, mutect2
- RGS12 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIMBP2 | c.1538T>A p.L513Q | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ROBO1 | c.2091A>T p.V697= | Splice Region (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- RPS6 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2
- RPS6KA4 | c.1973A>G p.D658G | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RUNX1T1 | c.1449G>T p.R483S (on ENST00000265814 / NM_001198628.1; = p.R456S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR1 | c.5747G>A p.G1916E | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.041); called by muse, mutect2
- SDR42E2 | c.659T>A p.L220Q | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- SELENBP1 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SEMA3A | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- SEMA3D | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 36/681 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.276); called by muse, mutect2
- SLC22A6 | c.1440G>T p.E480D | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.123); called by muse, mutect2
- SMS | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 19/439 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- SPATA31D1 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 29/619 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); called by muse, mutect2
- ST18 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST7 | c.1562G>T p.G521V (on ENST00000265437 / NM_021908.3; = p.G498V on NM_018412.4) | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2
- SV2A | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.8507A>T p.E2836V (on ENST00000367255 / NM_182961.4; = p.E2843V on NM_033071.3) | Missense Mutation (SNP) | VAF 20/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TAOK1 | c.2036G>T p.R679I | Missense Mutation (SNP) | VAF 44/626 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2
- TCOF1 | c.916C>A p.P306T (on ENST00000377797 / NM_001135243.1; = p.P229T on NM_000356.4) | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- TMEM121B | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TMEM123 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); called by muse, mutect2
- TMEM187 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- TMEM72 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TNXB | c.7582G>T p.A2528S (on ENST00000647633; = p.A2281S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, varscan2
- TRPV4 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- TSGA13 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- TSHZ2 | c.1567A>T p.T523S | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TTC6 | c.1835G>T p.R612I | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ZNF219 | c.1565-2A>T p.X522_splice | Splice Site (SNP) | VAF 14/141 reads (10%) | called by muse, mutect2
- ZNF80 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- A2M | c.1800G>T p.V600= | Silent (SNP) | VAF 36/442 reads (8%) | called by muse, mutect2
- ADAM20 | c.1083A>G p.L361= | Silent (SNP) | VAF 13/165 reads (8%) | catalogued as rs374483967; called by muse, mutect2
- ADCY10 | c.3891C>T p.Y1297= | Silent (SNP) | VAF 46/680 reads (7%) | catalogued as rs777383170, COSV63238873, COSV63241431; called by muse, mutect2
- ALAS2 | c.1023G>A p.E341= | Silent (SNP) | VAF 19/288 reads (7%) | called by muse, mutect2
- ARAP3 | c.1338G>A p.E446= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- ARSH | c.552C>A p.P184= | Silent (SNP) | VAF 42/485 reads (9%) | called by muse, mutect2
- BTBD8 | c.1704G>A p.E568= (on ENST00000636805 / NM_001376131.1; = p.E55= on NM_015237.4) | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- CACNA2D3 | c.750A>G p.A250= | Silent (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- CSMD3 | c.2976C>G p.S992= (on ENST00000297405 / NM_001363185.1; = p.S888= on NM_052900.3) | Silent (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- CYLD | c.2748G>A p.L916= | Silent (SNP) | VAF 7/158 reads (4%) | called by muse, mutect2
- DPY19L2 | c.807G>T p.G269= | Silent (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2, varscan2
- DRD1 | c.930C>G p.S310= | Silent (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- ENOX1 | c.1931A>G p.*644= | Silent (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- FAM155A | c.636C>T p.P212= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- FLNC | c.7029C>T p.G2343= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs770236960, COSV57967287; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR174 | c.870C>A p.V290= | Silent (SNP) | VAF 11/173 reads (6%) | called by muse, mutect2
- GRID2 | c.1680C>A p.A560= | Silent (SNP) | VAF 20/699 reads (3%) | called by muse, mutect2
- IPMK | c.1203T>C p.Y401= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- KLHL1 | c.702C>T p.S234= | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as rs766173867, COSV64780037; called by muse, mutect2
- LILRB4 | c.492A>C p.L164= | Silent (SNP) | VAF 18/283 reads (6%) | called by muse, mutect2
- LPAR2 | c.921C>G p.R307= | Silent (SNP) | VAF 8/167 reads (5%) | called by muse, mutect2
- LTBP1 | c.3723G>T p.T1241= (on ENST00000404816 / NM_206943.4; = p.T915= on NM_000627.4) | Silent (SNP) | VAF 19/292 reads (7%) | called by muse, mutect2
- MAGEA11 | c.1182C>A p.T394= | Silent (SNP) | VAF 41/230 reads (18%) | called by muse, mutect2, varscan2
- MOB2 | c.444G>T p.L148= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- MROH7 | c.327C>T p.S109= | Silent (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- MYL1 | c.81C>A p.A27= | Silent (SNP) | VAF 28/378 reads (7%) | catalogued as COSV61681550; called by muse, mutect2
- MYO7A | c.5028A>T p.P1676= | Silent (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- MYPN | c.3687C>A p.A1229= | Silent (SNP) | VAF 48/679 reads (7%) | called by muse, mutect2
- NGFR | c.1041G>A p.V347= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99413115; called by muse, mutect2
- NLN | c.1557T>C p.N519= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV66766521; called by muse, mutect2
- NR1I2 | c.1080C>A p.R360= | Silent (SNP) | VAF 16/269 reads (6%) | called by muse, mutect2
- OR5D18 | c.78C>A p.V26= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV61736385; called by muse, mutect2
- OR5P3 | c.387C>T p.P129= | Silent (SNP) | VAF 21/215 reads (10%) | catalogued as rs926386244, COSV60429597; called by muse, mutect2
- PAPOLG | c.1875C>G p.A625= | Silent (SNP) | VAF 27/358 reads (8%) | called by muse, mutect2
- PARP1 | c.1113C>T p.P371= | Silent (SNP) | VAF 44/329 reads (13%) | catalogued as rs746280132; called by muse, mutect2, varscan2
- PCDH15 | c.5130T>A p.P1710= | Silent (SNP) | VAF 44/580 reads (8%) | called by muse, mutect2
- PGAM4 | c.126G>T p.G42= | Silent (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- POLR3B | c.3075G>T p.R1025= | Silent (SNP) | VAF 27/261 reads (10%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1657C>T p.L553= | Silent (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- PRR33 | c.69C>A p.P23= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- PXDNL | c.2184C>T p.R728= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as rs746553805, COSV62480672; called by muse, mutect2, varscan2
- RFPL1 | c.15A>T p.S5= | Silent (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- RPS4X | c.273C>T p.S91= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as rs1403888889; called by muse, mutect2
- RYR1 | c.14925C>T p.G4975= | Silent (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- SLC52A3 | c.237G>T p.L79= | Silent (SNP) | VAF 41/481 reads (9%) | called by muse, mutect2
- SLX4 | c.909C>G p.L303= | Silent (SNP) | VAF 8/225 reads (4%) | called by muse, mutect2
- TAF1 | c.1767C>A p.P589= (on ENST00000373790 / NM_138923.4; = p.P610= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- TAGLN3 | c.546G>A p.K182= | Silent (SNP) | VAF 14/292 reads (5%) | called by muse, mutect2
- TEX13C | c.2574G>T p.L858= | Silent (SNP) | VAF 25/325 reads (8%) | called by muse, mutect2
- TGIF2LX | c.378G>T p.T126= | Silent (SNP) | VAF 86/546 reads (16%) | called by muse, mutect2, varscan2
- TYRP1 | c.510G>T p.L170= | Silent (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- ZIC1 | c.906T>C p.F302= | Silent (SNP) | VAF 8/211 reads (4%) | called by muse, mutect2
- ACSL6 | c.915+12A>T | Intron (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- AL132655.6 | chr20:58840549 T>A | 5'Flank (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- ASPH | c.104-5516G>A | Intron (SNP) | VAF 9/245 reads (4%) | called by muse, mutect2
- BCORL1 | c.4306-2768C>A | Intron (SNP) | VAF 33/483 reads (7%) | called by muse, mutect2
- C1orf112 | chr1:169795129 T>C | 5'Flank (SNP) | VAF 16/310 reads (5%) | catalogued as rs886719777; called by muse, mutect2
- C5orf17 | n.245G>T | RNA (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CAPRIN2 | c.2602-147G>T | Intron (SNP) | VAF 13/413 reads (3%) | called by muse, mutect2
- COL4A2 | c.1432+284G>T | Intron (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- DNAAF1 | c.2066-11T>A | Intron (SNP) | VAF 22/363 reads (6%) | called by muse, mutect2
- GULP1 | c.399+90G>T | Intron (SNP) | VAF 9/143 reads (6%) | called by muse, mutect2
- HERC2P2 | n.1570A>G | RNA (SNP) | VAF 26/592 reads (4%) | called by muse, mutect2
- LAIR2 | c.-80T>C | 5'UTR (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2, varscan2
- MINDY4B | chr3:150907411 T>A | 5'Flank (SNP) | VAF 21/256 reads (8%) | called by muse, mutect2
- NCF1B | n.456C>A | RNA (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- NPR3 | c.*3084T>G | 3'UTR (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99422737; called by mutect2, varscan2
- OR2M1P | n.398C>T | RNA (SNP) | VAF 20/248 reads (8%) | catalogued as rs1302837845; called by muse, mutect2
- PNLIPRP1 | c.331-366C>A | Intron (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- SCN3A | c.4807+51C>T | Intron (SNP) | VAF 12/145 reads (8%) | catalogued as rs375478472; called by muse, mutect2
- SHROOM4 | c.*205G>T | 3'UTR (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- TAAR3P | n.667G>T | RNA (SNP) | VAF 19/324 reads (6%) | called by muse, mutect2
- TP53TG3D | c.*205G>T | 3'UTR (SNP) | VAF 32/447 reads (7%) | called by muse, mutect2
- VWF | c.7730-31del | Intron (DEL) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- ZNF507 | c.2245+36T>C | Intron (SNP) | VAF 8/110 reads (7%) | catalogued as rs1266960583; called by muse, mutect2
